Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4746, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4746-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:
Sigmoid cancer.

Specimens Submitted:

- 1: SP: Sigmoid colon
- 2: SP: Proximal donut
- 3: SP: Distal donut

DIAGNOSIS:

1. LARGE BOWEL, SIGMOID; RESECTION;
- TUMOR TYPE: ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: SIGMOID.
- TUMOR SIZE: LENGTH IS 4.4 CM, WIDTH IS 3.7 CM.
- GROSS CONFIGURATION: FUNGATING.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): IDENTIFIED, OF TUBULOVILLOUS TYPE.
- TUMOR INVASION: INVASION INTO MUSCULARIS PROPRIA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NUMBER IDENTIFIED: MULTIPLE, TYPE IDENTIFIED: HYPERPLASTIC POLYP.
- TATTOO PIGMENT IS NOTED INVOLVING MUSCULARIS PROPRIA IN THE AREA ADJACENT TO THE TUMOR, CONSISTENT WITH PRIOR BIOPSY SITE.
- THE PATHOLOGIC STAGE IS [REDACTED]: pT2 TUMOR INVADES MUSCULARIS PROPRIA.
- LYMPH NODES: NUMBER WITH METASTASES: 0, NUMBER EXAMINED: 17.
- THE PATHOLOGIC STAGE IS [REDACTED]: pN0 NO REGIONAL LYMPH NODE METASTASES ARE IDENTIFIED.
2. COLON, PROXIMAL DONUT; EXCISION;
- UNREMARKABLE COLONIC TISSUE.
3. COLON, DISTAL DONUT; EXCISION;
- UNREMARKABLE COLONIC TISSUE.

** Continued on next page **

[page 2 of 3]
Page 2 of 3
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

1.) The specimen is received fresh and is labeled "sigmoid colon". It consists of a segment of colon that measures 13.8 cm in length by 6.8 cm in circumference at proximal resection margin (inked yellow) and 8.0 cm in circumference at distal resection margin (inked blue). The serosal surface is smooth. The specimen is opened to reveal a pink fungating tumor that is located 4.0 cm from the distal margin and 4.2 cm from proximal margin. The tumor measures 4.4 cm in length and 3.7 cm in width. Serial sectioning reveals tumor invasion to a depth of 0.1 cm, which is 0.5 cm from the serosa. The remaining mucosa shows at least 16 polyps measuring from 0.2 to 0.4 cm in greatest dimension. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. The tumor is entirely submitted. TPS is submitted.

Summary of sections:
PM -- proximal margin
DM -- distal margin
T -- tumor
U -- uninvolved mucosa
P -- polyps
LN -- lymph nodes

2). The specimen is received in formalin, labeled "proximal donut" and consists of a ring of pink tan soft tissue measuring 2 x 2 x 1.5 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

3). The specimen is received in formalin, labeled "Distal donut" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.2 x 1.3 cm. the mucosa is removed and entirely submitted.

Summary of sections:
U--undesignated

** Continued on next page **

[page 3 of 3]
Summary of Sections:

Part 1: SP: Sigmoid colon

Block	Sect.	Site	PCs
1		dm	1
6		ln	18
5		P	5
1		pm	1
3		t	3
1		u	1

Part 2: SP: Proximal donut

Block	Sect.	Site	PCs
1		u	1

Part 3: SP: Distal donut

Block	Sect.	Site	PCs
1		u	1

** End of Report **

Source: NCI Genomic Data Commons file 69599531-7ea3-46e4-bd59-a9e06be0e4cd (TCGA-CM-4746.BC55F7BB-DF41-4DD7-B11D-03405027396A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).